Gene-level copy-number profile of tumor specimen ALCH-B49V-TTP1-A from ALCHEMIST case ALCH-B49V, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.4 years (19,854 days).
Specimen ALCH-B49V-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fd26afee-4635-48f2-bd34-1c994ebdd003.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B49V-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/5b8cffd2-ee03-494d-b745-615be93adbcd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 183; copy number 1: 6,761; copy number 2: 50,920; copy number 3: 496; copy number 4: 12; copy number 5: 8; copy number 6: 1; copy number 8: 2; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 183 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,934,205–11,975,538, 1 gene: PLOD1.
- chr1:20,664,014–20,718,017, 2 genes: KIF17, AL663074.2.
- chr1:31,652,263–31,704,319, 1 gene (within-gene range 0–2): COL16A1.
- chr2:97,000,436–97,001,593, 1 gene (within-gene range 0–2): AC079395.3.
- chr3:194,355,249–194,369,743, 1 gene: LRRC15.
- chr6:106,969,831–106,975,627, 1 gene: CD24.
- chr7:40,151,613–40,154,151, 1 gene (within-gene range 0–2): THUMPD3P1.
- chr7:76,510,525–76,541,459, 5 genes: UPK3B, AC004980.4, Y_RNA, AC004980.3, SPDYE16.
- chr7:98,252,379–98,310,441, 1 gene (within-gene range 0–1): BRI3.
- chr7:102,285,091–102,329,530, 3 genes: SH2B2, MIR4285, AC091390.1.
- chr9:21,695,176–23,438,700, 22 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr9:60,914,407–64,473,826, 87 genes (broad region; genes not listed).
- chr9:124,257,606–124,353,307, 3 genes (within-gene range 0–1): NEK6, AL162724.2, AL162724.1.
- chr10:101,570,560–101,705,119, 7 genes (within-gene range 0–2): DPCD, POLL, MIR3158-1, MIR3158-2, FBXW4, RNU6-1165P, AC010789.2.
- chr11:70,603,304–70,604,859, 1 gene (within-gene range 0–2): AP001271.2.
- chr11:70,646,165–70,706,068, 3 genes (within-gene range 0–2): SHANK2-AS2, Y_RNA, AP000590.1.
- chr12:54,076,838–54,081,903, 1 gene (within-gene range 0–2): AC023794.3.
- chr14:23,372,809–23,408,273, 4 genes: IL25, CMTM5, MYH6, MIR208A.
- chr14:23,415,339–23,418,063, 2 genes (within-gene range 0–2): AL132855.1, MIR208B.
- chr14:90,820,064–90,828,199, 1 gene: LINC02321.
- chr14:102,582,888–102,583,177, 1 gene: RN7SL546P.
- chr15:25,222,348–25,241,827, 12 genes (within-gene range 0–2): SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39.
- chr17:81,539,885–81,553,961, 1 gene: FAAP100.
- chr18:14,143,596–14,151,139, 1 gene: AC006557.2.
- chr19:35,014,961–35,040,449, 2 genes (within-gene range 0–2): AC020907.4, SCN1B.
- chr19:41,425,359–41,428,730, 2 genes (within-gene range 0–2): AC011462.2, B3GNT8.
- chr19:53,599,628–53,682,245, 14 genes: AC011487.2, OSTCP3, RN7SL317P, DPRX, RNU6-698P, AC011453.2, MIR512-1, MIR512-2, MIR1323, MIR498, MIR520E, MIR515-1, MIR519E, MIR520F.
- chr20:37,903,111–37,945,350, 1 gene: VSTM2L.
- chr21:17,296,219–17,296,596, 1 gene: AP000457.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:75,391,955–75,416,787, 3 genes, copy number 6–8 (within-gene range 1–8): AC211486.1, TRIM73, NSUN5P1.
- chr9:136,738,167–136,780,218, 7 genes, copy number 5: LCN10, AL355987.1, LCN6, MIR6722, LCN8, LCN15, ATP6V1G1P3.
- chr19:637,105–637,537, 1 gene, copy number 5: AC004449.1.
- chr19:2,037,465–2,051,244, 1 gene, copy number 11: MKNK2.

Autosomal genes at a single copy (total copy number 1): 6,736. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
